Somatic mutation profile of tumor specimen TCGA-XR-A8TC-01A (aliquot TCGA-XR-A8TC-01A-11D-A35Z-10) from TCGA case TCGA-XR-A8TC, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 43.3 years (15,817 days).
Specimen TCGA-XR-A8TC-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ef9a2704-090e-4a72-a313-ae425ac1ae22.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-XR-A8TC-10A (Blood Derived Normal), aliquot TCGA-XR-A8TC-10A-01D-A35Z-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4455a012-2bea-4cba-ac1d-1af0ee74f87f

The open-access MAF lists 54 somatic variants for this specimen: 44 protein-altering or splice-affecting, 10 silent.
By variant classification: Missense Mutation 37, Silent 10, Nonsense Mutation 3, Splice Site 1, Frame Shift Del 1, Frame Shift Ins 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAM11 | c.1443C>A p.H481Q | Missense Mutation (SNP) | VAF 26/65 reads (40%) | SIFT tolerated (0.55); PolyPhen benign (0.371); catalogued as COSV99567266; called by muse, mutect2, varscan2
- ADAM18 | c.404G>T p.R135I | Missense Mutation (SNP) | VAF 42/746 reads (6%) | SIFT tolerated (0.2); PolyPhen benign (0.062); catalogued as rs549488812, COSV55856065, COSV99695279; called by muse, mutect2
- APC | c.1504G>A p.G502R | Missense Mutation (SNP) | VAF 47/116 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as COSV57355255, COSV99966709; called by muse, mutect2, varscan2
- APC | c.1505G>T p.G502V | Missense Mutation (SNP) | VAF 47/116 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.489); catalogued as COSV57335457, COSV99966710; called by muse, mutect2, varscan2
- ATXN7L2 | c.1868G>A p.R623Q | Missense Mutation (SNP) | VAF 65/102 reads (64%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.978); catalogued as rs377112437; called by muse, mutect2, varscan2
- AXIN1 | c.1657G>T p.E553* | Nonsense Mutation (SNP) | VAF 27/35 reads (77%) | catalogued as COSV51984661, COSV99249567; called by muse, mutect2, varscan2
- BTNL2 | c.727C>A p.L243M | Missense Mutation (SNP) | VAF 13/150 reads (9%) | SIFT tolerated (0.22); PolyPhen benign (0.03); catalogued as COSV100896030; called by muse, mutect2
- CCKAR | c.1172C>A p.P391H | Missense Mutation (SNP) | VAF 49/154 reads (32%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV99810212; called by muse, mutect2, varscan2
- CCKAR | c.1171C>A p.P391T | Missense Mutation (SNP) | VAF 50/154 reads (32%) | SIFT tolerated (0.58); PolyPhen benign (0.093); catalogued as COSV99810216; called by muse, mutect2, varscan2
- CDC42BPA | c.1891-1G>A p.X631_splice | Splice Site (SNP) | VAF 23/104 reads (22%) | catalogued as COSV100504358; called by muse, mutect2, varscan2
- CDKN1A | c.137G>T p.R46L | Missense Mutation (SNP) | VAF 40/73 reads (55%) | SIFT deleterious (0.02); PolyPhen benign (0.118); catalogued as COSV55188273, COSV55188826, COSV99781273; called by muse, mutect2, varscan2
- CHD4 | c.2733C>G p.F911L (on ENST00000357008 / NM_001363606.2; = p.F924L on NM_001273.5) | Missense Mutation (SNP) | VAF 44/96 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV100537652; called by muse, mutect2, varscan2
- CXCL12 | c.57C>G p.S19R | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs747891190, COSV100638902; called by muse, mutect2, varscan2
- DENND2B | c.2029C>T p.R677C | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.093); catalogued as rs768886391, COSV100567343; called by muse, mutect2, varscan2
- DOCK8 | c.3065C>T p.T1022I | Missense Mutation (SNP) | VAF 62/176 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.661); catalogued as COSV101209874; called by muse, mutect2, varscan2
- DRD3 | c.175G>T p.A59S | Missense Mutation (SNP) | VAF 60/137 reads (44%) | SIFT tolerated (0.47); PolyPhen benign (0.007); catalogued as COSV99879306; called by muse, mutect2, varscan2
- ERCC2 | c.971G>C p.R324P | Missense Mutation (SNP) | VAF 14/27 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99676176; called by muse, mutect2, varscan2
- FERMT2 | c.418C>G p.L140V | Missense Mutation (SNP) | VAF 26/57 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.506); catalogued as COSV100448827; called by muse, mutect2, varscan2
- FMO4 | c.62G>A p.C21Y | Missense Mutation (SNP) | VAF 83/164 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100882044; called by muse, mutect2, varscan2
- GARNL3 | c.1192C>T p.R398C | Missense Mutation (SNP) | VAF 38/99 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1270744732, COSV100150089; called by muse, mutect2, varscan2
- GPR52 | c.532T>C p.F178L | Missense Mutation (SNP) | VAF 24/139 reads (17%) | SIFT tolerated (0.49); PolyPhen benign (0.07); catalogued as COSV99269093; called by muse, mutect2, varscan2
- HOXB2 | c.771C>G p.S257R | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV100344532; called by muse, mutect2, varscan2
- INTS7 | c.895G>A p.A299T | Missense Mutation (SNP) | VAF 30/118 reads (25%) | SIFT tolerated (0.72); PolyPhen possibly damaging (0.766); catalogued as COSV100877452; called by muse, mutect2, varscan2
- IQGAP2 | c.4081G>C p.E1361Q | Missense Mutation (SNP) | VAF 149/356 reads (42%) | SIFT tolerated (0.23); PolyPhen benign (0.105); catalogued as COSV99166890; called by muse, mutect2, varscan2
- LILRA1 | c.86C>T p.P29L | Missense Mutation (SNP) | VAF 44/124 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99251835; called by muse, varscan2
- MACROH2A2 | c.82C>G p.L28V | Missense Mutation (SNP) | VAF 139/230 reads (60%) | SIFT tolerated (0.34); PolyPhen benign (0.023); catalogued as COSV100952313; called by muse, mutect2, varscan2
- MUC5B | c.17126G>A p.R5709Q | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT tolerated (0.21); PolyPhen benign (0.018); catalogued as rs372911529; called by muse, varscan2
- NANS | c.256C>T p.R86* | Nonsense Mutation (SNP) | VAF 58/151 reads (38%) | catalogued as rs752343283, COSV99271169; called by muse, mutect2, varscan2
- NLRP5 | c.374C>T p.T125M | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT tolerated (0.32); PolyPhen benign (0.04); catalogued as rs866571014, COSV66765210; called by muse, mutect2, varscan2
- NSD3 | c.3262C>T p.Q1088* | Nonsense Mutation (SNP) | VAF 48/150 reads (32%) | catalogued as COSV100395178; called by muse, mutect2, varscan2
- PCDH15 | c.823C>A p.R275S | Missense Mutation (SNP) | VAF 59/226 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.944); catalogued as COSV100218232; called by muse, mutect2, varscan2
- PDE8A | c.1132C>G p.H378D | Missense Mutation (SNP) | VAF 48/106 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.644); catalogued as COSV100051706; called by muse, mutect2
- PRAC1 | c.55A>G p.S19G | Missense Mutation (SNP) | VAF 36/92 reads (39%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.009); catalogued as COSV99284833; called by muse, mutect2, varscan2
- PRRC2B | c.1004G>A p.R335H | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.869); catalogued as rs766432428, COSV100621647; called by muse, mutect2, varscan2
- RBM28 | c.1331G>T p.R444L | Missense Mutation (SNP) | VAF 37/113 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99775589; called by muse, mutect2, varscan2
- RPTOR | c.3449G>T p.W1150L | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.005); catalogued as COSV100155789, COSV100157133; called by muse, mutect2, varscan2
- RPTOR | c.3450G>T p.W1150C | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.626); catalogued as COSV100155791, COSV60810705; called by muse, mutect2, varscan2
- STAB2 | c.1970T>C p.I657T | Missense Mutation (SNP) | VAF 129/204 reads (63%) | SIFT deleterious (0); PolyPhen possibly damaging (0.69); catalogued as rs979213833, COSV101185786; called by muse, mutect2, varscan2
- STK3 | c.757G>A p.D253N | Missense Mutation (SNP) | VAF 83/302 reads (27%) | SIFT tolerated (0.16); PolyPhen benign (0.255); catalogued as rs757271491, COSV101372464; called by muse, mutect2, varscan2
- TMEM132E | c.2245G>A p.A749T (on ENST00000321639; = p.A839T on NM_001304438.2) | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT tolerated (0.66); PolyPhen benign (0.013); catalogued as rs772406178, COSV100396077; called by muse, mutect2, varscan2
- VSIG4 | c.1000A>T p.M334L | Missense Mutation (SNP) | VAF 27/108 reads (25%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as COSV101038119; called by muse, mutect2, varscan2
- COL18A1 | c.313_315del p.E105del | In Frame Del (DEL) | VAF 36/100 reads (36%) | called by pindel, varscan2
- HADHA | c.1821del p.F607Lfs*13 | Frame Shift Del (DEL) | VAF 36/138 reads (26%) | called by pindel, varscan2
- IGHV3-13 | c.322delinsTT p.D108Lfs*? | Frame Shift Ins (INS) | VAF 13/44 reads (30%) | called by pindel, varscan2*
- CORO1B | c.129C>G p.V43= | Silent (SNP) | VAF 30/76 reads (39%) | catalogued as COSV100396371; called by muse, mutect2, varscan2
- DOCK7 | c.5304C>T p.Y1768= (on ENST00000635253 / NM_001367561.1; = p.Y1737= on NM_033407.3) | Silent (SNP) | VAF 161/215 reads (75%) | catalogued as rs1173529301, COSV99223769; called by muse, mutect2, varscan2
- KCNV2 | c.624C>T p.D208= | Silent (SNP) | VAF 35/78 reads (45%) | catalogued as COSV101172551; called by muse, mutect2, varscan2
- KRT33A | c.237G>T p.R79= | Silent (SNP) | VAF 43/114 reads (38%) | catalogued as COSV99144821; called by muse, mutect2, varscan2
- PCNX4 | c.2097T>G p.V699= (on ENST00000406854 / NM_001330177.2; = p.V465= on NM_022495.5) | Silent (SNP) | VAF 36/112 reads (32%) | catalogued as COSV100470137; called by muse, mutect2, varscan2
- SUV39H1 | c.381G>C p.A127= | Silent (SNP) | VAF 74/173 reads (43%) | catalogued as COSV100551723; called by muse, mutect2, varscan2
- TBC1D10A | c.192G>T p.S64= | Silent (SNP) | VAF 49/99 reads (49%) | catalogued as rs375400780; called by muse, mutect2, varscan2
- UBE2O | c.168G>C p.S56= | Silent (SNP) | VAF 80/165 reads (48%) | catalogued as COSV99166197; called by muse, mutect2, varscan2
- UNK | c.573G>A p.A191= | Silent (SNP) | VAF 37/84 reads (44%) | catalogued as rs768022967, COSV99504782; called by muse, mutect2, varscan2
- ZNF516 | c.1554C>T p.F518= | Silent (SNP) | VAF 28/70 reads (40%) | catalogued as rs1375979867, COSV101487238; called by muse, mutect2, varscan2
